Somatic mutation profile of tumor specimen C3N-03837-01 (aliquot CPT0236620006) from CPTAC case C3N-03837, project CPTAC-3 (Lip — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lip, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 54.1 years (19,778 days).
Specimen C3N-03837-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lip; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 010bc92d-a97a-4087-ba6d-e778faed4fc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03837-31 (Blood Derived Normal), aliquot CPT0236680002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc84c492-9294-4f8b-9fee-2da92b1e06c5

The open-access MAF lists 619 somatic variants for this specimen: 383 protein-altering or splice-affecting, 162 silent, 74 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 340, Silent 162, Intron 29, Nonsense Mutation 25, RNA 17, 3'UTR 11, Splice Site 9, Splice Region 7, 5'UTR 6, 5'Flank 6, 3'Flank 5, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 245/695 reads (35%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- HRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 165/460 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.487T>A p.Y163N | Missense Mutation (SNP) | VAF 63/264 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.8194G>A p.G2732R | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.951); catalogued as rs780836246; called by muse, mutect2, varscan2
- ABI3BP | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs770109610, COSV52528036; called by muse, mutect2, varscan2
- ADAM28 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.426); catalogued as COSV56099066; called by muse, mutect2
- ADAM28 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as rs1229935924; called by muse, mutect2
- ADAMTS14 | c.3550C>T p.P1184S | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs965506781; called by muse, mutect2, varscan2
- ADGRB3 | c.2875G>A p.V959I | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1371872262; called by muse, mutect2, varscan2
- AGBL2 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1565034949, COSV54094326; called by muse, mutect2, varscan2
- AKAP1 | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as rs1256480523; called by muse, mutect2, varscan2
- ALB | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as rs75709682, CM900419, COSV55741899; ClinVar: other; called by muse, mutect2, varscan2
- ANKRD30A | c.1078G>A p.E360K (on ENST00000611781; = p.E304K on NM_052997.2) | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs77379875; called by muse, mutect2, varscan2
- APBB2 | c.868C>T p.P290S (on ENST00000295974 / NM_001166050.2; = p.P291S on NM_004307.2) | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.754); catalogued as rs1374952887; called by muse, mutect2, varscan2
- AQP2 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 58/403 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772051028, CM024087, COSV52229934; called by muse, mutect2, varscan2
- ARHGAP33 | c.2698C>G p.Q900E | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as rs1432047872; called by muse, mutect2, varscan2
- ARMC4 | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs185614747, COSV59469540; called by muse, mutect2, varscan2
- ASIC3 | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs149180925; called by muse, mutect2, varscan2
- ATP10A | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV63524511; called by muse, mutect2
- ATP13A4 | c.2327T>A p.I776N | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV61321666; called by muse, mutect2, varscan2
- ATP2C2 | c.2074G>A p.G692R | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52294335, COSV52299463; called by muse, mutect2, varscan2
- BCAR1 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1231249529, COSV99366700; called by muse, mutect2, varscan2
- BMP5 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 59/374 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs866784947, COSV63701354; called by muse, mutect2, varscan2
- BPGM | c.160C>T p.L54F | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.334); catalogued as rs371168429; called by muse, mutect2, varscan2
- BRD4 | c.3760C>T p.R1254W | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1427595023; called by muse, mutect2, varscan2
- C4orf19 | c.152T>A p.V51E | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.432); catalogued as rs767060843; called by muse, mutect2, varscan2
- CASKIN1 | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 89/448 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as rs868700060; called by muse, mutect2, varscan2
- CASP8 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51847282; called by muse, varscan2
- CCDC30 | c.2035C>T p.P679S (on ENST00000340612; = p.P636S on NM_001080850.3) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.059); catalogued as COSV59608657; called by muse, mutect2, varscan2
- CCDC57 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 54/334 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CM1514089; called by muse, mutect2, varscan2
- CDH8 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV54857743; called by muse, mutect2, varscan2
- CEBPZ | c.2231G>A p.G744E | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs753447258; called by muse, mutect2, varscan2
- CENPF | c.1265C>T p.T422I | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs552331813; called by muse, mutect2, varscan2
- CER1 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as rs759221042, COSV66603625; called by muse, mutect2, varscan2
- CFAP46 | c.5446C>T p.Q1816* | Nonsense Mutation (SNP) | VAF 59/325 reads (18%) | catalogued as rs372585021; called by muse, mutect2, varscan2
- CHD5 | c.1182G>A p.W394* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV52423682; called by muse, mutect2, varscan2
- CNR1 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.647); catalogued as COSV62986979, COSV62990918; called by muse, mutect2, varscan2
- COLEC12 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV68370635; called by muse, mutect2, varscan2
- CRYZ | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as rs756850761, COSV100558473; called by muse, mutect2, varscan2
- CSMD1 | c.2626G>A p.D876N (on ENST00000520002; = p.D875N on NM_033225.6) | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100141608, COSV59283046; called by muse, mutect2, varscan2
- CSMD1 | c.2198G>A p.G733E (on ENST00000520002; = p.G732E on NM_033225.6) | Missense Mutation (SNP) | VAF 39/312 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100148719, COSV59276812; called by muse, mutect2, varscan2
- DGCR8 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 61/286 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100708198; called by muse, mutect2, varscan2
- DGCR8 | c.915C>A p.D305E | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.586); catalogued as rs530897530; called by muse, mutect2, varscan2
- DMRT3 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as rs375561407; called by muse, mutect2, varscan2
- DMXL2 | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs768229260, COSV99196652; called by muse, mutect2, varscan2
- DOT1L | c.3779C>T p.P1260L | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs780498768, COSV67111475; called by muse, mutect2, varscan2
- DPPA4 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59512570; called by muse, mutect2, varscan2
- DYNC1H1 | c.5978C>T p.T1993I | Missense Mutation (SNP) | VAF 61/368 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs750380197; called by muse, mutect2, varscan2
- EBF1 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58168973, COSV58177101; called by muse, mutect2, varscan2
- EPHA2 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 73/384 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV64452307; called by muse, mutect2, varscan2
- EPHA7 | c.2852C>T p.S951F | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as rs141581954, COSV100993692, COSV65182703; called by muse, mutect2, varscan2
- ERP44 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52431460; called by muse, mutect2, varscan2
- EXPH5 | c.2426C>T p.S809F | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as COSV56199607; called by muse, mutect2, varscan2
- FAM50A | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV50133399; called by muse, mutect2, varscan2
- FAT1 | c.13670C>T p.S4557F | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101499333, COSV101499527; called by muse, mutect2, varscan2
- FAT3 | c.5369G>A p.S1790N | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV53072963; called by muse, mutect2, varscan2
- FCRL5 | c.1823G>A p.G608E | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.791); catalogued as COSV62516618; called by muse, mutect2, varscan2
- FOXN1 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 67/350 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56881468; called by muse, mutect2, varscan2
- GCSAML | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs752847092, COSV63579911; called by muse, mutect2, varscan2
- GHRHR | c.160+1G>A p.X54_splice | Splice Site (SNP) | VAF 83/563 reads (15%) | catalogued as COSV58198271; called by muse, mutect2, varscan2
- GLRA2 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as COSV99491468; called by muse, mutect2, varscan2
- GLRA3 | c.1039C>T p.L347F | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as rs748841046; called by muse, mutect2, varscan2
- GUCY1A2 | c.2135C>T p.S712L | Missense Mutation (SNP) | VAF 51/337 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.574); catalogued as rs1383258563, COSV56477773; called by muse, mutect2, varscan2
- HJV | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 45/346 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV60953435; called by muse, varscan2
- HORMAD1 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs774953907, COSV55048098; called by muse, mutect2, varscan2
- IRGC | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.871); catalogued as rs1041254422, COSV54986508; called by muse, mutect2, varscan2
- ISYNA1 | c.1355C>T p.T452I | Missense Mutation (SNP) | VAF 62/399 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.218); catalogued as rs1418168194; called by muse, mutect2, varscan2
- ITGAX | c.1456C>A p.Q486K | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.069); catalogued as rs1187107364; called by muse, mutect2
- KANK2 | c.2260G>A p.V754I (on ENST00000586659 / NM_001379562.1; = p.V762I on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/379 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.348); catalogued as rs749771260, COSV62007653; called by muse, mutect2, varscan2
- KCNH5 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV59781122; called by muse, mutect2, varscan2
- KCNK2 | c.1066C>T p.Q356* (on ENST00000444842 / NM_001017425.3; = p.Q341* on NM_014217.4) | Nonsense Mutation (SNP) | VAF 45/239 reads (19%) | catalogued as COSV67206474; called by muse, mutect2, varscan2
- KDM4A | c.2464C>T p.P822S | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1314993948; called by muse, mutect2, varscan2
- KIAA1109 | c.11824C>T p.P3942S | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as rs1459679324, COSV52661856; called by muse, mutect2, varscan2
- KRTAP12-3 | c.7C>T p.H3Y | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV59970108; called by muse, mutect2, varscan2
- LETM1 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 69/425 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs750908839; called by muse, mutect2, varscan2
- LIPI | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs914640060; called by muse, mutect2, varscan2
- LMTK2 | c.4192C>T p.P1398S | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.044); catalogued as rs778384389; called by muse, mutect2, varscan2
- LRP1B | c.6142G>A p.D2048N | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67238170; called by muse, mutect2
- LRP5 | c.3174G>A p.M1058I | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs974024634; called by muse, mutect2, varscan2
- M1AP | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.096); catalogued as COSV99284026; called by muse, mutect2, varscan2
- MAP2 | c.5164C>T p.R1722C | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749308409, COSV52281337; called by muse, mutect2, varscan2
- MAP3K21 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 56/376 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157699639, COSV100786320; called by muse, mutect2, varscan2
- MDN1 | c.6745C>T p.P2249S | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.68); catalogued as rs148747464; called by muse, mutect2, varscan2
- MED12 | c.931G>A p.G311S | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.214); catalogued as rs1477622307; called by muse, mutect2, varscan2
- MERTK | c.1769G>A p.G590E | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99775123; called by muse, mutect2, varscan2
- MESP1 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs756503571; called by muse, mutect2, varscan2
- MEX3D | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 53/408 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs749343553, COSV66312102; called by muse, mutect2, varscan2
- MPHOSPH8 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs776707000; called by muse, mutect2, varscan2
- MUC16 | c.25238C>T p.S8413F | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.74); catalogued as COSV67494269; called by muse, mutect2
- MYH11 | c.5131G>A p.E1711K | Missense Mutation (SNP) | VAF 72/493 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as rs267604421; called by muse, mutect2, varscan2
- MYH11 | c.4993C>A p.R1665S | Missense Mutation (SNP) | VAF 106/551 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55556793; called by muse, mutect2, varscan2
- MYH4 | c.2064G>A p.M688I | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV55117483; called by muse, mutect2, varscan2
- MYH7 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs1566535805; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK2 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 79/473 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs549697670, COSV65659036; called by muse, mutect2, varscan2
- MYLK3 | c.2188G>A p.D730N | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV67364526; called by muse, mutect2, varscan2
- MYO10 | c.1070G>C p.R357T | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.033); catalogued as COSV72563105; called by muse, mutect2, varscan2
- MYO15B | c.5594C>T p.S1865F | Missense Mutation (SNP) | VAF 40/294 reads (14%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.794); catalogued as rs1250310342; called by muse, mutect2, varscan2
- MYO7B | c.5113G>A p.A1705T | Missense Mutation (SNP) | VAF 43/287 reads (15%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.527); catalogued as rs774261637; called by muse, mutect2, varscan2
- MYOCD | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 69/277 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58501714; called by muse, varscan2
- NAGPA | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 29/166 reads (17%) | PolyPhen benign (0.011); catalogued as rs1169475682; called by muse, mutect2, varscan2
- NALCN | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs1166728490, COSV51925068, COSV51934163; called by muse, mutect2, varscan2
- NCAM2 | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs757374731, COSV53082619; called by muse, mutect2, varscan2
- NEK6 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs750746819, COSV100206774; called by muse, mutect2, varscan2
- NFATC3 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as rs1267655453; called by muse, mutect2, varscan2
- NIBAN3 | c.1666G>A p.G556R | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs1172449647; called by muse, mutect2, varscan2
- NUTM2G | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 70/958 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as rs778682136; called by muse, mutect2
- NXPE4 | c.1028G>A p.G343E (on ENST00000375478 / NM_001077639.2; = p.G59E on NM_017678.3) | Missense Mutation (SNP) | VAF 44/335 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1475472547, COSV64943713; called by muse, mutect2, varscan2
- OPTC | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 79/385 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1199977046; called by muse, mutect2, varscan2
- OR6C1 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs945432077; called by muse, mutect2, varscan2
- OR9G4 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 62/303 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57248637; called by muse, mutect2, varscan2
- OSMR | c.1343C>T p.T448I | Missense Mutation (SNP) | VAF 62/435 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs971359882; called by muse, mutect2, varscan2
- OTOF | c.3710C>T p.S1237L (on ENST00000272371 / NM_194248.3; = p.S490L on NM_004802.4) | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as rs753598510; called by muse, mutect2, varscan2
- OVCH1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58961330, COSV58962647; called by muse, mutect2, varscan2
- P2RY13 | c.776T>C p.V259A | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as rs754980456; called by muse, mutect2, varscan2
- PAN2 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as COSV57754126; called by mutect2, varscan2
- PARM1 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 66/395 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1039671801, COSV56649794; called by muse, mutect2, varscan2
- PARM1 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs368728639; called by muse, mutect2, varscan2
- PCDH10 | c.541G>C p.A181P | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as COSV52094374; called by muse, mutect2, varscan2
- PDYN | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757917060; called by muse, mutect2, varscan2
- PDZD7 | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 51/293 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs772930835; called by muse, mutect2, varscan2
- PHLDA3 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 110/696 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs115057664; called by muse, mutect2
- PICK1 | c.835-8C>T | Splice Region (SNP) | VAF 56/229 reads (24%) | catalogued as rs369930998; called by muse, mutect2, varscan2
- PILRA | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 50/307 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs780522436; called by muse, mutect2, varscan2
- PINX1 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV59108154; called by muse, mutect2, varscan2
- PLEC | c.8821C>T p.R2941C (on ENST00000322810 / NM_201380.4; = p.R2831C on NM_000445.5) | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs369084664; called by muse, mutect2, varscan2
- PLEC | c.5968G>A p.E1990K (on ENST00000322810 / NM_201380.4; = p.E1880K on NM_000445.5) | Missense Mutation (SNP) | VAF 81/541 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1554696968; called by muse, mutect2, varscan2
- PLEKHA4 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs267605570; called by muse, mutect2, varscan2
- PLXNA1 | c.1774C>T p.L592F | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs201695917, COSV99302967; called by muse, mutect2, varscan2
- PPP1R9A | c.3144G>A p.M1048I | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV99195296; called by muse, mutect2, varscan2
- PRB1 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs776461033; called by muse, varscan2
- PRKCZ | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs779910797, COSV100423129, COSV100423131; called by muse, mutect2, varscan2
- PROX1 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV54775764; called by muse, mutect2, varscan2
- PTPN23 | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.491); catalogued as rs753290716; called by muse, mutect2
- RASSF7 | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 44/354 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs1380121485; called by muse, mutect2, varscan2
- RFWD3 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 60/407 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs1307003739; called by muse, mutect2, varscan2
- RIMS2 | c.2959C>A p.R987S (on ENST00000666250 / NM_001348490.2; = p.R795S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs1312275741, COSV51651310; called by muse, mutect2, varscan2
- RINL | c.1195G>T p.G399W (on ENST00000591812 / NM_001195833.2; = p.G285W on NM_198445.4) | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV61574677; called by muse, mutect2, varscan2
- RNF157 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as COSV99487125; called by muse, mutect2, varscan2
- ROCK2 | c.3268G>T p.E1090* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | catalogued as COSV59954664; called by muse, mutect2
- RUNDC3A | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV56588308; called by muse, mutect2, varscan2
- RYR2 | c.5836G>A p.E1946K | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as rs267598436, COSV63689111; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAFB2 | c.2180C>T p.P727L | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs770640751; called by muse, mutect2
- SAFB2 | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs532158958; called by muse, mutect2
- SATB2 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.297); catalogued as rs768080548; called by muse, mutect2, varscan2
- SBSN | c.1522G>A p.E508K (on ENST00000452271 / NM_001166034.2; = p.E165K on NM_198538.4) | Missense Mutation (SNP) | VAF 59/374 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.501); catalogued as COSV71733107; called by muse, mutect2, varscan2
- SERPINB11 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1355365574, COSV66956404; called by muse, mutect2, varscan2
- SETDB2 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV51645967; called by muse, mutect2, varscan2
- SLC15A1 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.56); catalogued as rs1050096674; called by muse, mutect2, varscan2
- SLC15A5 | c.1351C>T p.L451F | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867519711; called by muse, mutect2, varscan2
- SLC17A8 | c.920G>A p.W307* | Nonsense Mutation (SNP) | VAF 19/122 reads (16%) | catalogued as rs765214819; called by muse, mutect2, varscan2
- SLC17A8 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 45/281 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs755212082, COSV60121740; called by muse, mutect2, varscan2
- SLC1A6 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 66/379 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as COSV99694027; called by muse, mutect2, varscan2
- SLC25A34 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV53816412; called by muse, mutect2, varscan2
- SLC6A15 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57030293; called by muse, mutect2, varscan2
- SLC9C1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs749177716, COSV59886093; called by muse, mutect2, varscan2
- SLIT2 | c.324-1G>A p.X108_splice | Splice Site (SNP) | VAF 27/165 reads (16%) | catalogued as COSV56563625, COSV56595240; called by muse, mutect2, varscan2
- SMAD3 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 73/332 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100528662; called by muse, mutect2, varscan2
- SMAD3 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 74/339 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59279965; called by muse, mutect2, varscan2
- SMURF2 | c.91+1G>A p.X31_splice | Splice Site (SNP) | VAF 13/80 reads (16%) | catalogued as rs1555689073, COSV52320351; called by muse, mutect2, varscan2
- SPIRE2 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV65557674; called by muse, mutect2, varscan2
- TARS3 | c.1394C>G p.S465* | Nonsense Mutation (SNP) | VAF 19/114 reads (17%) | catalogued as COSV60107580; called by muse, mutect2, varscan2
- TCHH | c.5086G>A p.E1696K | Missense Mutation (SNP) | VAF 90/537 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); catalogued as rs767309998, COSV64274166; called by muse, mutect2, varscan2
- TCTE3 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as rs200990438; called by muse, mutect2, varscan2
- TEX14 | c.1036C>T p.P346S (on ENST00000240361 / NM_001201457.2; = p.P340S on NM_031272.5) | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769392618, COSV53627324; called by muse, mutect2, varscan2
- TMEM184A | c.77dup p.P27Tfs*126 | Frame Shift Ins (INS) | VAF 19/166 reads (11%) | catalogued as rs757773044; called by mutect2, pindel, varscan2
- TMEM63A | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.094); catalogued as rs1277972538; called by muse, mutect2, varscan2
- TMEM67 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.149); catalogued as COSV60044324; called by muse, mutect2
- TNXB | c.12835G>A p.E4279K (on ENST00000647633; = p.E4032K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/469 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64481284; called by muse, mutect2, varscan2
- TOP2B | c.4694C>T p.S1565F (on ENST00000264331 / NM_001330700.2; = p.S1560F on NM_001068.3) | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as COSV51968360; called by muse, mutect2, varscan2
- TRMT9B | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.081); catalogued as rs370869117; called by muse, mutect2, varscan2
- TRPM4 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs766805975, COSV53264269; called by muse, mutect2, varscan2
- TTC8 | c.458C>T p.T153M (on ENST00000338104 / NM_001288781.1; = p.T163M on NM_144596.4) | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758942370, COSV57626212; called by muse, mutect2, varscan2
- TTN | c.81839G>A p.G27280E (on ENST00000591111; = p.G19856E on NM_003319.4) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | PolyPhen probably damaging (0.912); catalogued as rs1553559912, COSV60324131; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.60236C>T p.P20079L (on ENST00000591111; = p.P12655L on NM_003319.4) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | PolyPhen possibly damaging (0.67); catalogued as rs878854325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.1097C>T p.T366I | Missense Mutation (SNP) | VAF 55/310 reads (18%) | PolyPhen benign (0.186); catalogued as COSV99046004; called by muse, mutect2
- UBR2 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV65769851; called by muse, mutect2, varscan2
- WNK4 | c.792-6C>T | Splice Region (SNP) | VAF 16/95 reads (17%) | catalogued as rs1432458416; called by muse, mutect2, varscan2
- ZDHHC14 | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 88/526 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV58194806; called by muse, mutect2, varscan2
- ZFYVE1 | c.838C>T p.L280F | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59611374; called by muse, mutect2, varscan2
- ZIM2 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV55649641; called by muse, mutect2, varscan2
- ZNF404 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs35756172, COSV60987968; called by mutect2, varscan2
- ZNF716 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101348452, COSV70782755; called by muse, mutect2, varscan2
- ZNF804A | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56439839; called by muse, varscan2
- ZNF804A | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV56447252; called by muse, varscan2
- ZNF823 | c.1043G>A p.R348Q (on ENST00000341191 / NM_001297610.2; = p.R304Q on NM_017507.2) | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT tolerated (0.98); PolyPhen benign (0.042); catalogued as rs1408809958, COSV57872586; called by muse, mutect2, varscan2
- ABCA4 | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 47/253 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- ABCB5 | c.3222G>A p.V1074= (on ENST00000404938 / NM_001163941.2; = p.V629= on NM_178559.6) | Splice Region (SNP) | VAF 40/204 reads (20%) | called by muse, mutect2, varscan2
- ADAD2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS16 | c.3127C>A p.L1043M | Missense Mutation (SNP) | VAF 76/425 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ADCY3 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRV1 | c.13795C>A p.H4599N | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- AHNAK2 | c.4891C>T p.P1631S | Missense Mutation (SNP) | VAF 108/654 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALPG | c.677T>G p.M226R | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ALPK2 | c.3972_3975delinsCTAA p.W1325* | Nonsense Mutation (ONP) | VAF 10/84 reads (12%) | called by mutect2*, pindel, varscan2*
- ANK1 | c.4325C>T p.S1442F | Missense Mutation (SNP) | VAF 104/577 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ANK3 | c.2815G>A p.E939K (on ENST00000280772 / NM_001320874.2; = p.E73K on NM_001149.3) | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ANKRD12 | c.4345C>T p.Q1449* | Nonsense Mutation (SNP) | VAF 26/149 reads (17%) | called by muse, mutect2, varscan2
- ANKRD24 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ARHGAP35 | c.2926C>T p.P976S | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ARHGAP35 | c.2927C>T p.P976L | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- ARHGAP45 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- ARMH3 | c.954G>A p.Q318= | Splice Region (SNP) | VAF 19/143 reads (13%) | called by muse, mutect2, varscan2
- ATP10D | c.498A>T p.K166N | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.246); called by muse, mutect2
- BATF2 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.56); called by muse, varscan2
- BCL9 | c.1716A>T p.E572D | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- BDP1 | c.5014C>T p.P1672S | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- BPTF | c.5864C>T p.P1955L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2
- BRINP1 | c.1693A>C p.N565H | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BRSK1 | c.1598G>A p.G533E | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- C10orf67 | c.909G>A p.K303= | Splice Region (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- C16orf71 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- C1orf167 | c.4294C>T p.P1432S | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, varscan2
- C7 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CAMK2B | c.839C>A p.S280Y | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CASKIN2 | c.875T>A p.F292Y | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CASP8 | c.28A>T p.I10F | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CBFA2T2 | c.517T>C p.F173L | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- CCDC114 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- CEACAM6 | c.45G>A p.W15* | Nonsense Mutation (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- CELSR1 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CFAP46 | c.6820G>A p.E2274K | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); called by muse, mutect2
- CHD5 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CHRNB4 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CLEC9A | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CLIP1 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL19A1 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- COL4A2 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A6 | c.347G>A p.R116K | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL9A1 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 71/412 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CREBBP | c.6555G>A p.M2185I | Missense Mutation (SNP) | VAF 130/790 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- CREBBP | c.5471C>T p.A1824V | Missense Mutation (SNP) | VAF 87/402 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CRISPLD2 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CRNN | c.1064C>T p.T355I | Missense Mutation (SNP) | VAF 53/390 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- CSMD1 | c.1388G>A p.G463D (on ENST00000520002; = p.G462D on NM_033225.6) | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTNNA2 | c.2619G>A p.M873I (on ENST00000402739 / NM_001282597.3; = p.M825I on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2
- CWF19L1 | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DDX20 | c.2168T>C p.L723P | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND1B | c.489_491del p.D163_Q164delinsE | In Frame Del (DEL) | VAF 16/108 reads (15%) | called by mutect2, pindel, varscan2
- DMTF1 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH8 | c.8036C>T p.A2679V | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DUOX2 | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 75/443 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DZIP3 | c.2424-1G>A p.X808_splice | Splice Site (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- EDRF1 | c.2441A>C p.E814A (on ENST00000356792 / NM_001202438.2; = p.E780A on NM_015608.2) | Missense Mutation (SNP) | VAF 45/327 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EGR4 | c.950G>A p.G317E (on ENST00000545030; = p.G214E on NM_001965.4) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EP300 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.235); called by mutect2, varscan2
- EP300 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- EPB41L3 | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- EPHA5 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM160A1 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- FAM162A | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- FER | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FOXP3 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- FOXP3 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GEMIN5 | c.2600G>A p.C867Y | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPR21 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 49/297 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GRK3 | c.1298T>G p.V433G | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- HAPLN4 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- HLA-B | c.895+1G>C p.X299_splice | Splice Site (SNP) | VAF 34/258 reads (13%) | called by muse, varscan2
- HR | c.2216C>T p.S739F | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- HSD17B11 | c.850A>T p.K284* | Nonsense Mutation (SNP) | VAF 20/136 reads (15%) | called by muse, mutect2, varscan2
- HTR3B | c.1015T>G p.F339V | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HTR4 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 19/164 reads (12%) | PolyPhen possibly damaging (0.692); called by muse, mutect2
- IFI16 | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGDCC4 | c.1501T>C p.F501L | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ING2 | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IPO13 | c.2741C>T p.P914L | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- IPO4 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- IRS1 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITPR3 | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- JAK1 | c.856T>A p.F286I | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KALRN | c.3524G>A p.G1175E | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KCNK16 | c.511G>A p.G171S | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.065); called by muse, mutect2
- KCNQ3 | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 48/335 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- KDM8 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KIAA1522 | c.712G>A p.D238N (on ENST00000373480 / NM_001198972.2; = p.D297N on NM_020888.3) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- KIRREL3 | c.74G>A p.R25K | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- KLF8 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LMTK3 | c.4192C>T p.P1398S | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.447); called by muse, mutect2
- LRGUK | c.1688A>G p.D563G | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- LRP5 | c.3175G>A p.G1059R | Missense Mutation (SNP) | VAF 49/251 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAML2 | c.1915C>T p.Q639* | Nonsense Mutation (SNP) | VAF 100/618 reads (16%) | called by muse, varscan2
- MAPK8IP1 | c.715C>G p.R239G | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- MBD5 | c.3751C>T p.P1251S | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.109); called by muse, mutect2
- MED14 | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- MGAM | c.4258-1G>A p.X1420_splice | Splice Site (SNP) | VAF 44/254 reads (17%) | called by muse, mutect2, varscan2
- MSTO1 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTHFD1L | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- MUC4 | c.15515C>T p.P5172L (on ENST00000463781 / NM_018406.7; = p.P936L on NM_004532.6) | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- MYH7B | c.4948G>A p.D1650N | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2
- MYOM3 | c.2548C>T p.P850S | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- NAGPA | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 29/164 reads (18%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- NDST2 | c.215C>G p.P72R | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- NME9 | c.670A>C p.S224R (on ENST00000333911 / NM_001349024.2; = p.S163R on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NONO | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRG3 | c.1904A>T p.N635I (on ENST00000404547 / NM_001370084.1; = p.N611I on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/315 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- NRK | c.1682T>G p.V561G | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- NUAK2 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUP160 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2
- NUP160 | c.526-1G>A p.X176_splice | Splice Site (SNP) | VAF 21/133 reads (16%) | called by muse, mutect2
- NUTM2F | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.305); called by muse, varscan2
- OR4C11 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); called by mutect2, varscan2
- OSBPL6 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OSCAR | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 51/285 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PCDHA13 | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 58/352 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCNT | c.2339C>T p.S780F | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- PCSK5 | c.2850C>A p.C950* | Nonsense Mutation (SNP) | VAF 26/132 reads (20%) | called by muse, mutect2, varscan2
- PDGFRB | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 56/302 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- PFN3 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 79/377 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PGBD2 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PGRMC2 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PIK3R6 | c.1617C>A p.Y539* | Nonsense Mutation (SNP) | VAF 19/116 reads (16%) | called by muse, mutect2, varscan2
- PLCG2 | c.648+1G>A p.X216_splice | Splice Site (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2
- PLEKHA4 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PLEKHG1 | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLPPR3 | c.1720G>A p.D574N (on ENST00000520876 / NM_001270366.2; = p.D602N on NM_024888.2) | Missense Mutation (SNP) | VAF 72/358 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- PNPLA8 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- POGZ | c.2681C>T p.P894L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.036); called by muse, mutect2
- POGZ | c.2680C>T p.P894S | Missense Mutation (SNP) | VAF 2/42 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- PRAMEF20 | c.647G>A p.W216* | Nonsense Mutation (SNP) | VAF 142/851 reads (17%) | called by muse, mutect2, varscan2
- PRICKLE1 | c.633G>A p.W211* | Nonsense Mutation (SNP) | VAF 57/285 reads (20%) | called by muse, varscan2
- PROM1 | c.1062T>G p.D354E | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PSMB11 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTCHD1 | c.1367G>A p.W456* | Nonsense Mutation (SNP) | VAF 34/118 reads (29%) | called by muse, mutect2, varscan2
- PTDSS2 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 160/459 reads (35%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- PXDN | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- PZP | c.2278G>A p.V760I | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- QPRT | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RAB17 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASGRF1 | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGS3 | c.2026C>T p.P676S (on ENST00000350696 / NM_001282923.2; = p.P564S on NM_017790.4) | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RHOBTB1 | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROCK2 | c.3684C>A p.F1228L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- SBNO2 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCAPER | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCART1 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SCN11A | c.4031C>T p.P1344L | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SCNN1D | c.1787G>A p.G596D (on ENST00000338555; = p.G760D on NM_001130413.4) | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLC12A2 | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, varscan2
- SLC12A5 | c.2848G>A p.E950K (on ENST00000454036 / NM_001134771.2; = p.E927K on NM_020708.5) | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2
- SLC15A5 | c.1350C>T p.A450= | Splice Region (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2, varscan2
- SLC22A31 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 54/295 reads (18%) | called by muse, mutect2, varscan2
- SLC9A8 | c.959-1G>A p.X320_splice | Splice Site (SNP) | VAF 42/174 reads (24%) | called by muse, mutect2
- SLIT1 | c.3110G>A p.G1037E | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- SNW1 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SP140L | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SPART | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPOCK3 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SPOP | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- STXBP5L | c.1280T>C p.L427P | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SVEP1 | c.5816G>A p.G1939D | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- SVEP1 | c.5815G>A p.G1939S | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- TAF1L | c.3876G>A p.M1292I | Missense Mutation (SNP) | VAF 116/375 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- TIRAP | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- TJP3 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM86A | c.160C>T p.L54F | Missense Mutation (SNP) | VAF 89/437 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- TMPRSS3 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 86/540 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TNFRSF12A | c.200G>A p.C67Y | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- TOPBP1 | c.4144C>T p.Q1382* | Nonsense Mutation (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- TRAV8-1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- TRIM47 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRPC1 | c.1231G>A p.D411N (on ENST00000476941 / NM_001251845.2; = p.D377N on NM_003304.4) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- TTN | c.67933G>T p.G22645* (on ENST00000591111; = p.G15221* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- U2SURP | c.2459C>T p.P820L | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- UBA6 | c.1932G>C p.K644N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE2I | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- UGT1A5 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- UNC5C | c.2750G>A p.G917E | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VIPR2 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- WDR77 | c.51G>A p.W17* | Nonsense Mutation (SNP) | VAF 31/199 reads (16%) | called by muse, mutect2, varscan2
- WDR87 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- WFIKKN1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- WNK4 | c.792-7C>T | Splice Region (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- XIRP2 | c.7259A>T p.E2420V (on ENST00000628543; = p.E2595V on NM_152381.6) | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XKR8 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- ZMYND8 | c.864T>G p.F288L (on ENST00000311275 / NM_001363741.2; = p.F308L on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ZNF146 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- ZNF358 | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 59/266 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF610 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF69 | c.744T>G p.Y248* | Nonsense Mutation (SNP) | VAF 17/152 reads (11%) | called by muse, mutect2, varscan2
- ZNF727 | c.956A>C p.K319T | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF729 | c.3343A>G p.N1115D | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- ZNF74 | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN1 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 68/348 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- AC136428.1 | c.298C>T p.L100= | Silent (SNP) | VAF 55/364 reads (15%) | called by muse, mutect2, varscan2
- ACTN2 | c.1860C>T p.I620= | Silent (SNP) | VAF 93/546 reads (17%) | catalogued as COSV100857054; called by mutect2, varscan2
- ADAMTS14 | c.3549C>T p.T1183= | Silent (SNP) | VAF 20/109 reads (18%) | called by muse, mutect2, varscan2
- ADGRF3 | c.2928C>T p.L976= (on ENST00000311519 / NM_001145168.1; = p.L777= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/269 reads (16%) | called by muse, mutect2, varscan2
- ALPK3 | c.3429C>T p.F1143= | Silent (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- ANKEF1 | c.1029C>T p.A343= | Silent (SNP) | VAF 21/152 reads (14%) | called by muse, mutect2, varscan2
- ARMC4 | c.1515C>G p.T505= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV100537474; called by muse, mutect2, varscan2
- ASAP3 | c.2172G>T p.G724= | Silent (SNP) | VAF 24/106 reads (23%) | called by muse, mutect2, varscan2
- ASPHD1 | c.501G>A p.R167= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs1201930188; called by muse, mutect2, varscan2
- ATP10A | c.223C>T p.L75= | Silent (SNP) | VAF 39/261 reads (15%) | catalogued as rs532896913; called by muse, mutect2, varscan2
- B3GNT7 | c.1101C>T p.F367= | Silent (SNP) | VAF 61/368 reads (17%) | catalogued as rs145105825; called by muse, mutect2, varscan2
- BAHCC1 | c.6855G>A p.K2285= | Silent (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2, varscan2
- BRSK1 | c.1599G>A p.G533= | Silent (SNP) | VAF 40/174 reads (23%) | called by muse, mutect2, varscan2
- BTBD16 | c.633C>T p.I211= | Silent (SNP) | VAF 49/335 reads (15%) | called by muse, mutect2, varscan2
- C1orf131 | c.571C>T p.L191= | Silent (SNP) | VAF 38/282 reads (13%) | called by muse, mutect2, varscan2
- C1orf167 | c.4293C>T p.S1431= | Silent (SNP) | VAF 41/335 reads (12%) | called by muse, varscan2
- CACNA1B | c.1296G>A p.E432= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs748329454; called by muse, mutect2, varscan2
- CAMTA2 | c.2985C>T p.F995= | Silent (SNP) | VAF 38/139 reads (27%) | called by muse, mutect2, varscan2
- CASKIN2 | c.876C>T p.F292= | Silent (SNP) | VAF 25/214 reads (12%) | called by muse, mutect2, varscan2
- CCDC157 | c.714C>T p.V238= | Silent (SNP) | VAF 79/415 reads (19%) | called by muse, mutect2, varscan2
- CCT8L2 | c.525C>T p.S175= | Silent (SNP) | VAF 53/227 reads (23%) | catalogued as COSV63462056; called by muse, mutect2, varscan2
- CDK4 | c.762C>T p.P254= | Silent (SNP) | VAF 32/197 reads (16%) | catalogued as rs753908111; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CEACAM3 | c.39C>T p.I13= | Silent (SNP) | VAF 30/201 reads (15%) | catalogued as rs1484720325; called by muse, mutect2, varscan2
- CEP128 | c.120G>A p.K40= | Silent (SNP) | VAF 32/147 reads (22%) | catalogued as COSV53674745; called by muse, mutect2, varscan2
- CEP152 | c.3117C>T p.I1039= | Silent (SNP) | VAF 66/390 reads (17%) | catalogued as rs576054020; called by muse, mutect2, varscan2
- CEP85L | c.945G>A p.E315= | Silent (SNP) | VAF 54/262 reads (21%) | called by muse, mutect2, varscan2
- CFAP46 | c.5445C>T p.A1815= | Silent (SNP) | VAF 58/323 reads (18%) | catalogued as rs1458420659; called by muse, mutect2, varscan2
- CHCHD7 | c.123C>T p.F41= (on ENST00000355315 / NM_001011671.3; = p.F53= on NM_024300.4) | Silent (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2, varscan2
- CHRNA6 | c.954C>T p.I318= | Silent (SNP) | VAF 32/311 reads (10%) | catalogued as rs201833648; called by muse, mutect2
- CLASRP | c.75G>A p.R25= | Silent (SNP) | VAF 29/222 reads (13%) | called by muse, mutect2, varscan2
- COL4A2 | c.369G>A p.P123= | Silent (SNP) | VAF 18/143 reads (13%) | catalogued as rs769155086, COSV100847071; called by muse, mutect2, varscan2
- CRY2 | c.1227C>T p.F409= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV69889089; called by muse, mutect2, varscan2
- CRYBB1 | c.504G>A p.G168= | Silent (SNP) | VAF 116/698 reads (17%) | catalogued as rs1017163439, COSV53234008; called by muse, mutect2, varscan2
- CSMD2 | c.10434C>T p.F3478= | Silent (SNP) | VAF 52/257 reads (20%) | called by muse, mutect2, varscan2
- CTDSP1 | c.222C>T p.T74= | Silent (SNP) | VAF 29/170 reads (17%) | called by muse, mutect2, varscan2
- CTSE | c.144C>T p.S48= | Silent (SNP) | VAF 25/130 reads (19%) | called by muse, mutect2, varscan2
- CUX1 | c.2127C>T p.I709= | Silent (SNP) | VAF 38/248 reads (15%) | called by muse, mutect2, varscan2
- CUX1 | c.2128C>T p.L710= | Silent (SNP) | VAF 38/252 reads (15%) | catalogued as rs1434496975; called by muse, mutect2, varscan2
- CYP2C8 | c.81G>A p.R27= | Silent (SNP) | VAF 35/183 reads (19%) | catalogued as COSV64876989; called by muse, mutect2, varscan2
- DCAF4L1 | c.1056C>T p.I352= | Silent (SNP) | VAF 38/259 reads (15%) | catalogued as COSV60787302; called by muse, mutect2, varscan2
- DDX60L | c.732G>A p.Q244= | Silent (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- DMXL1 | c.8799C>A p.A2933= | Silent (SNP) | VAF 34/276 reads (12%) | called by muse, mutect2, varscan2
- DNAH5 | c.8220C>T p.I2740= | Silent (SNP) | VAF 57/354 reads (16%) | catalogued as rs763401841, COSV99456536; called by muse, mutect2, varscan2
- DSCAML1 | c.3018G>A p.Q1006= (on ENST00000321322; = p.Q946= on NM_020693.4) | Silent (SNP) | VAF 28/170 reads (16%) | called by muse, mutect2, varscan2
- EGR4 | c.951G>A p.G317= (on ENST00000545030; = p.G214= on NM_001965.4) | Silent (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- ERBB4 | c.462C>T p.F154= | Silent (SNP) | VAF 21/173 reads (12%) | catalogued as rs749011668, COSV53537437; called by muse, mutect2, varscan2
- ERCC6L2 | c.4146C>T p.S1382= | Silent (SNP) | VAF 45/250 reads (18%) | called by muse, mutect2, varscan2
- ERICH6B | c.1758C>T p.I586= | Silent (SNP) | VAF 49/304 reads (16%) | called by muse, mutect2, varscan2
- ESCO2 | c.264C>T p.N88= | Silent (SNP) | VAF 16/120 reads (13%) | called by muse, mutect2, varscan2
- ETV6 | c.1320G>A p.Q440= | Silent (SNP) | VAF 33/196 reads (17%) | catalogued as rs12231057; called by muse, mutect2, varscan2
- FAM50A | c.774C>T p.I258= | Silent (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- FCGR3B | c.171C>T p.S57= | Silent (SNP) | VAF 64/762 reads (8%) | catalogued as COSV99670753; called by muse, mutect2
- FCRL5 | c.1824G>A p.G608= | Silent (SNP) | VAF 21/172 reads (12%) | catalogued as rs776442047, COSV62511999; called by muse, mutect2, varscan2
- FGA | c.2088C>T p.F696= | Silent (SNP) | VAF 54/294 reads (18%) | catalogued as rs1024393205, COSV57392374; called by muse, mutect2, varscan2
- FREM3 | c.3279C>T p.L1093= | Silent (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- FSIP2 | c.5202G>A p.A1734= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs568599074, COSV58084044; called by muse, mutect2, varscan2
- G6PC | c.933C>T p.S311= | Silent (SNP) | VAF 54/314 reads (17%) | called by muse, mutect2, varscan2
- GET1-SH3BGR | c.501C>T p.F167= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs749361535; called by muse, mutect2
- GRXCR1 | c.48C>T p.V16= | Silent (SNP) | VAF 31/168 reads (18%) | called by muse, mutect2, varscan2
- GZMH | c.87C>T p.P29= | Silent (SNP) | VAF 28/185 reads (15%) | catalogued as rs759866455, COSV99362110; called by muse, mutect2, varscan2
- H1-3 | c.147G>A p.V49= | Silent (SNP) | VAF 40/301 reads (13%) | catalogued as rs369209295; called by muse, mutect2, varscan2
- H3C3 | c.84G>A p.K28= | Silent (SNP) | VAF 39/238 reads (16%) | catalogued as rs773505635; called by muse, mutect2, varscan2
- HSPA8 | c.750G>A p.K250= | Silent (SNP) | VAF 44/278 reads (16%) | catalogued as rs776678845; called by muse, mutect2, varscan2
- HSPH1 | c.2004C>T p.L668= | Silent (SNP) | VAF 21/147 reads (14%) | called by muse, mutect2, varscan2
- HTR4 | c.147C>T p.S49= | Silent (SNP) | VAF 18/168 reads (11%) | catalogued as rs1318340591; called by muse, mutect2
- IFNL3 | c.345G>T p.L115= | Silent (SNP) | VAF 43/245 reads (18%) | called by muse, mutect2, varscan2
- IGHV3-48 | c.249G>A p.V83= | Silent (SNP) | VAF 44/561 reads (8%) | catalogued as rs1555530586; called by muse, mutect2
- IGKV3D-11 | c.174G>A p.Q58= | Silent (SNP) | VAF 101/767 reads (13%) | catalogued as rs755317612; called by muse, mutect2, varscan2
- ITPR3 | c.5394G>A p.Q1798= | Silent (SNP) | VAF 37/222 reads (17%) | called by muse, mutect2, varscan2
- KCNK16 | c.510G>A p.L170= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as rs765424840; called by muse, mutect2
- KCTD18 | c.1221C>A p.P407= | Silent (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- KDM4A | c.2463C>T p.I821= | Silent (SNP) | VAF 23/229 reads (10%) | called by muse, mutect2, varscan2
- KDM8 | c.1026C>T p.S342= | Silent (SNP) | VAF 40/261 reads (15%) | called by muse, mutect2, varscan2
- KEAP1 | c.1224C>T p.P408= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs776084785; called by muse, mutect2, varscan2
- KLHL14 | c.1233G>A p.Q411= | Silent (SNP) | VAF 41/250 reads (16%) | called by muse, mutect2, varscan2
- KRT23 | c.1098G>A p.K366= | Silent (SNP) | VAF 78/402 reads (19%) | called by muse, mutect2, varscan2
- KY | c.1911C>T p.V637= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as rs750617998, COSV101414999; called by muse, mutect2, varscan2
- LAIR1 | c.657G>A p.R219= | Silent (SNP) | VAF 8/61 reads (13%) | called by muse, varscan2
- LCE4A | c.15G>A p.Q5= | Silent (SNP) | VAF 15/101 reads (15%) | called by muse, mutect2, varscan2
- LRTOMT | c.271C>T p.L91= | Silent (SNP) | VAF 54/304 reads (18%) | called by muse, mutect2, varscan2
- MAB21L2 | c.894C>T p.D298= | Silent (SNP) | VAF 28/153 reads (18%) | called by muse, mutect2, varscan2
- MC4R | c.819G>A p.Q273= | Silent (SNP) | VAF 24/163 reads (15%) | catalogued as COSV55351270; called by muse, mutect2, varscan2
- MC5R | c.657C>T p.I219= | Silent (SNP) | VAF 40/225 reads (18%) | catalogued as rs747840339, COSV61255214; called by muse, mutect2, varscan2
- MKI67 | c.3240C>T p.A1080= | Silent (SNP) | VAF 66/369 reads (18%) | called by muse, mutect2, varscan2
- MUC16 | c.25239C>T p.S8413= | Silent (SNP) | VAF 24/277 reads (9%) | called by muse, mutect2
- MYO15A | c.2004G>A p.R668= | Silent (SNP) | VAF 18/76 reads (24%) | called by muse, varscan2
- MYO1B | c.1602C>T p.L534= | Silent (SNP) | VAF 37/180 reads (21%) | called by muse, mutect2, varscan2
- NLRP9 | c.2820G>A p.P940= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs138948455; called by muse, mutect2, varscan2
- NONO | c.1122C>T p.F374= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs1187056675; called by muse, mutect2, varscan2
- ODF2 | c.2172G>A p.R724= (on ENST00000434106 / NM_153433.2; = p.R700= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- OR10X1 | c.448C>T p.L150= | Silent (SNP) | VAF 31/254 reads (12%) | called by muse, mutect2, varscan2
- OR5AN1 | c.909G>A p.K303= | Silent (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- OR8B12 | c.750C>T p.F250= | Silent (SNP) | VAF 28/153 reads (18%) | called by muse, mutect2, varscan2
- OSGEP | c.159C>T p.I53= | Silent (SNP) | VAF 45/231 reads (19%) | called by muse, mutect2, varscan2
- OTOG | c.2589G>A p.L863= | Silent (SNP) | VAF 28/210 reads (13%) | called by muse, mutect2
- PARD3 | c.3576C>T p.S1192= | Silent (SNP) | VAF 49/286 reads (17%) | catalogued as rs745473559, COSV100630800; called by muse, mutect2, varscan2
- PCDHB1 | c.2088C>A p.V696= | Silent (SNP) | VAF 32/142 reads (23%) | called by muse, varscan2
- PCDHB14 | c.2046G>A p.Q682= | Silent (SNP) | VAF 110/633 reads (17%) | called by muse, mutect2, varscan2
- PCDHB3 | c.2193C>G p.P731= | Silent (SNP) | VAF 39/252 reads (15%) | catalogued as COSV50619504; called by muse, mutect2, varscan2
- PDX1 | c.519G>A p.R173= | Silent (SNP) | VAF 40/256 reads (16%) | called by muse, mutect2, varscan2
- PGP | c.276C>T p.P92= | Silent (SNP) | VAF 31/137 reads (23%) | called by muse, mutect2, varscan2
- PIGO | c.921C>T p.F307= | Silent (SNP) | VAF 38/194 reads (20%) | catalogued as COSV53053323; called by muse, mutect2, varscan2
- PLCG1 | c.3246C>T p.L1082= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as rs1284667325; called by muse, mutect2, varscan2
- PLD2 | c.1956G>A p.T652= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs1180332028; called by muse, mutect2, varscan2
- PLEC | c.5967G>A p.A1989= (on ENST00000322810 / NM_201380.4; = p.A1879= on NM_000445.5) | Silent (SNP) | VAF 78/535 reads (15%) | catalogued as rs782115169; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNC1 | c.4254C>T p.F1418= | Silent (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- PMS2 | c.321G>T p.R107= | Silent (SNP) | VAF 46/352 reads (13%) | catalogued as rs756420858; ClinVar: likely benign; called by muse, mutect2, varscan2
- POTEC | c.156C>T p.S52= | Silent (SNP) | VAF 71/399 reads (18%) | catalogued as COSV100743115; called by muse, mutect2, varscan2
- POU5F1 | c.69G>A p.G23= | Silent (SNP) | VAF 26/113 reads (23%) | called by muse, mutect2, varscan2
- PPFIA1 | c.312C>T p.L104= | Silent (SNP) | VAF 10/111 reads (9%) | catalogued as rs1321236140; called by muse, mutect2
- PROSER1 | c.1584G>A p.Q528= | Silent (SNP) | VAF 60/308 reads (19%) | catalogued as COSV100612572, COSV61485899; called by muse, mutect2, varscan2
- PTCD2 | c.375C>T p.F125= | Silent (SNP) | VAF 28/168 reads (17%) | catalogued as COSV57339152; called by muse, mutect2, varscan2
- PWWP3B | c.1203G>A p.Q401= | Silent (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- PXDN | c.4386C>T p.I1462= | Silent (SNP) | VAF 43/288 reads (15%) | catalogued as rs1208979684; called by muse, mutect2, varscan2
- RABGGTA | c.1101G>A p.E367= | Silent (SNP) | VAF 46/290 reads (16%) | called by muse, mutect2, varscan2
- RELN | c.6843C>T p.P2281= | Silent (SNP) | VAF 77/388 reads (20%) | called by muse, mutect2, varscan2
- RGS3 | c.2025C>T p.P675= (on ENST00000350696 / NM_001282923.2; = p.P563= on NM_017790.4) | Silent (SNP) | VAF 35/174 reads (20%) | called by muse, mutect2, varscan2
- RIC1 | c.4116C>T p.P1372= | Silent (SNP) | VAF 68/208 reads (33%) | called by muse, mutect2, varscan2
- RYR2 | c.12591C>T p.I4197= | Silent (SNP) | VAF 41/206 reads (20%) | called by muse, mutect2, varscan2
- SBF1 | c.3576C>T p.F1192= | Silent (SNP) | VAF 58/316 reads (18%) | called by muse, mutect2, varscan2
- SCNN1D | c.468G>A p.R156= (on ENST00000338555; = p.R320= on NM_001130413.4) | Silent (SNP) | VAF 46/245 reads (19%) | catalogued as COSV57640176; called by muse, mutect2, varscan2
- SHANK3 | c.3306C>T p.A1102= | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- SLC17A6 | c.465C>T p.F155= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs771516965, COSV54138604; called by muse, mutect2, varscan2
- SLC22A6 | c.1116G>A p.V372= | Silent (SNP) | VAF 53/413 reads (13%) | catalogued as COSV64559943; called by muse, mutect2, varscan2
- SLC22A6 | c.573C>T p.F191= | Silent (SNP) | VAF 46/258 reads (18%) | catalogued as rs1192882000; called by muse, mutect2, varscan2
- SLC9A2 | c.504G>A p.T168= | Silent (SNP) | VAF 41/202 reads (20%) | catalogued as rs267598814, COSV52128348, COSV52134766; called by muse, mutect2, varscan2
- SNAP47 | c.1098G>A p.E366= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as COSV104410470; called by muse, mutect2, varscan2
- SPATA31A6 | c.684C>T p.P228= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs1326535466; called by mutect2, varscan2
- SPIC | c.603C>T p.L201= | Silent (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- SPTA1 | c.1905C>T p.T635= | Silent (SNP) | VAF 62/408 reads (15%) | called by muse, mutect2, varscan2
- SRL | c.1206G>A p.K402= | Silent (SNP) | VAF 35/173 reads (20%) | called by muse, mutect2, varscan2
- SRRM2 | c.8187C>T p.S2729= | Silent (SNP) | VAF 44/232 reads (19%) | called by muse, mutect2, varscan2
- STOML2 | c.165C>T p.F55= | Silent (SNP) | VAF 84/214 reads (39%) | called by muse, mutect2, varscan2
- TAS2R7 | c.63C>T p.I21= | Silent (SNP) | VAF 20/135 reads (15%) | called by muse, mutect2, varscan2
- TBX5 | c.1308C>G p.V436= | Silent (SNP) | VAF 58/378 reads (15%) | called by muse, mutect2, varscan2
- TET1 | c.3789C>T p.L1263= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as rs367864439, COSV65387604; called by muse, mutect2, varscan2
- TEX14 | c.1035C>T p.F345= (on ENST00000240361 / NM_001201457.2; = p.F339= on NM_031272.5) | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as rs887683524; called by muse, mutect2, varscan2
- THSD7A | c.2856G>A p.E952= | Silent (SNP) | VAF 33/234 reads (14%) | called by muse, mutect2, varscan2
- TIRAP | c.531C>T p.P177= | Silent (SNP) | VAF 45/223 reads (20%) | called by muse, mutect2, varscan2
- TMEM201 | c.159G>A p.Q53= | Silent (SNP) | VAF 54/334 reads (16%) | called by muse, varscan2
- TMPRSS3 | c.1143C>T p.S381= | Silent (SNP) | VAF 86/542 reads (16%) | called by muse, mutect2, varscan2
- TOP2B | c.4695C>T p.S1565= (on ENST00000264331 / NM_001330700.2; = p.S1560= on NM_001068.3) | Silent (SNP) | VAF 35/193 reads (18%) | called by muse, mutect2, varscan2
- TRABD2B | c.123C>T p.F41= | Silent (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- TRAV8-1 | c.276C>T p.S92= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- TRIM47 | c.1617C>T p.P539= | Silent (SNP) | VAF 29/226 reads (13%) | catalogued as rs1449242139; called by muse, mutect2, varscan2
- TRPM5 | c.270G>A p.K90= | Silent (SNP) | VAF 29/138 reads (21%) | catalogued as rs749036547; called by muse, mutect2, varscan2
- TTLL13P | c.2136T>C p.C712= | Silent (SNP) | VAF 37/196 reads (19%) | called by muse, mutect2, varscan2
- TUBA1C | c.795C>T p.I265= | Silent (SNP) | VAF 37/250 reads (15%) | called by muse, mutect2, varscan2
- URB1 | c.5118C>T p.S1706= | Silent (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2
- URGCP | c.2410C>T p.L804= (on ENST00000453200 / NM_001077663.3; = p.L795= on NM_017920.4) | Silent (SNP) | VAF 30/197 reads (15%) | called by muse, mutect2, varscan2
- USP40 | c.327G>A p.Q109= | Silent (SNP) | VAF 33/210 reads (16%) | called by muse, mutect2, varscan2
- VAV1 | c.2391C>T p.D797= | Silent (SNP) | VAF 19/217 reads (9%) | catalogued as COSV58378505; called by muse, mutect2
- VWA8 | c.3384C>T p.L1128= | Silent (SNP) | VAF 47/239 reads (20%) | catalogued as rs779325167; called by muse, mutect2, varscan2
- WDFY4 | c.7506G>A p.R2502= | Silent (SNP) | VAF 18/115 reads (16%) | called by muse, mutect2, varscan2
- YRDC | c.156G>A p.G52= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs1046806935; called by muse, mutect2, varscan2
- ZBTB42 | c.66C>T p.F22= | Silent (SNP) | VAF 26/148 reads (18%) | catalogued as rs889334614; called by muse, mutect2, varscan2
- ZFP90 | c.792C>T p.L264= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as rs992581277; called by muse, mutect2, varscan2
- ZFYVE1 | c.837C>T p.F279= | Silent (SNP) | VAF 27/207 reads (13%) | catalogued as rs746985816, COSV59612207; called by muse, mutect2, varscan2
- ZNF222 | c.795C>T p.S265= | Silent (SNP) | VAF 40/323 reads (12%) | called by muse, mutect2, varscan2
- ZNF679 | c.288C>T p.D96= | Silent (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2
- ZNF793 | c.1134G>A p.Q378= | Silent (SNP) | VAF 31/186 reads (17%) | called by muse, mutect2, varscan2
- ZNF879 | c.1377G>A p.K459= | Silent (SNP) | VAF 32/207 reads (15%) | called by muse, mutect2, varscan2
- AC093512.2 | c.*1648C>T | 3'UTR (SNP) | VAF 42/151 reads (28%) | called by muse, mutect2, varscan2
- AC134312.1 | n.1288T>C | RNA (SNP) | VAF 33/168 reads (20%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9545G>A | Intron (SNP) | VAF 116/638 reads (18%) | called by muse, mutect2, varscan2
- ACACB | c.6497-410C>T | Intron (SNP) | VAF 35/179 reads (20%) | called by muse, mutect2, varscan2
- AFAP1 | c.1645+49T>G | Intron (SNP) | VAF 41/251 reads (16%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849975 G>A | 5'Flank (SNP) | VAF 28/92 reads (30%) | catalogued as rs758439155; called by muse, mutect2, varscan2
- AP000679.1 | n.396G>A | RNA (SNP) | VAF 27/149 reads (18%) | called by muse, mutect2, varscan2
- ARL10 | chr5:176386730 C>T | 3'Flank (SNP) | VAF 33/177 reads (19%) | catalogued as rs1260429519; called by muse, mutect2, varscan2
- ASIC1 | c.559-3119G>T | Intron (SNP) | VAF 23/90 reads (26%) | catalogued as rs1365973374; called by muse, mutect2, varscan2
- C11orf40 | n.428C>T | RNA (SNP) | VAF 23/121 reads (19%) | catalogued as rs1336068935, COSV56891498; called by muse, mutect2, varscan2
- C19orf54 | c.*708G>A | 3'UTR (SNP) | VAF 23/142 reads (16%) | called by muse, mutect2, varscan2
- CHRND | c.*541C>T | 3'UTR (SNP) | VAF 72/409 reads (18%) | called by muse, mutect2, varscan2
- CLCN5 | c.17-29044G>A | Intron (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- CLUHP11 | n.280G>A | RNA (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- CNN2 | c.654+64C>T | Intron (SNP) | VAF 36/177 reads (20%) | catalogued as rs781011021; called by muse, mutect2
- COLEC11 | chr2:3595054 C>T | 5'Flank (SNP) | VAF 21/111 reads (19%) | called by muse, mutect2, varscan2
- CTTN | c.*1219C>T | 3'UTR (SNP) | VAF 43/195 reads (22%) | catalogued as rs1056940776; called by muse, mutect2, varscan2
- DCHS2 | n.2290G>A | RNA (SNP) | VAF 22/194 reads (11%) | catalogued as rs1280861047, COSV100252008; called by muse, mutect2, varscan2
- DNAH8 | c.-155G>A | 5'UTR (SNP) | VAF 7/57 reads (12%) | catalogued as COSV59483673; called by muse, mutect2, varscan2
- ECH1 | c.475-42C>T | Intron (SNP) | VAF 23/115 reads (20%) | catalogued as rs751494082; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446611 G>A | 3'Flank (SNP) | VAF 75/402 reads (19%) | catalogued as rs201145036; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446795 C>A | 3'Flank (SNP) | VAF 56/318 reads (18%) | called by mutect2, varscan2
- FOXR1 | c.612-201G>A | Intron (SNP) | VAF 53/276 reads (19%) | called by muse, mutect2, varscan2
- GRAMD1B | c.1085-45C>T | Intron (SNP) | VAF 63/404 reads (16%) | called by muse, mutect2, varscan2
- GRHPR | c.734+104G>A | Intron (SNP) | VAF 61/413 reads (15%) | called by muse, mutect2, varscan2
- HIPK1 | chr1:113929469 C>T | 5'Flank (SNP) | VAF 63/429 reads (15%) | called by muse, mutect2, varscan2
- IGF2 | c.326-484C>T | Intron (SNP) | VAF 19/106 reads (18%) | catalogued as rs537385465; called by muse, mutect2, varscan2
- IGFN1 | c.1241+2856G>A | Intron (SNP) | VAF 29/247 reads (12%) | catalogued as rs775420995; called by muse, mutect2, varscan2
- IGFN1 | c.1242-2433A>G | Intron (SNP) | VAF 53/391 reads (14%) | catalogued as rs756526914; called by muse, mutect2, varscan2
- IGHEP1 | n.512G>A | RNA (SNP) | VAF 60/496 reads (12%) | called by muse, varscan2
- IGHEP1 | n.511G>A | RNA (SNP) | VAF 61/499 reads (12%) | catalogued as rs762638513; called by muse, varscan2
- IKZF1 | c.161-8418A>G | Intron (SNP) | VAF 38/228 reads (17%) | catalogued as rs773787303; called by muse, mutect2, varscan2
- ITGA7 | c.2135+27G>A | Intron (SNP) | VAF 32/152 reads (21%) | called by muse, mutect2, varscan2
- JAG2 | c.2394-18C>T | Intron (SNP) | VAF 125/601 reads (21%) | called by muse, mutect2, varscan2
- KNTC1 | c.5497-66G>A | Intron (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2
- LINC01549 | n.410C>T | RNA (SNP) | VAF 24/145 reads (17%) | called by muse, mutect2, varscan2
- LRRC23 | c.-1G>A | 5'UTR (SNP) | VAF 16/115 reads (14%) | catalogued as COSV99145385; called by muse, mutect2, varscan2
- MAP1A | c.-108T>G | 5'UTR (SNP) | VAF 14/108 reads (13%) | catalogued as COSV55807394; called by muse, mutect2
- MED24 | c.937-17C>T | Intron (SNP) | VAF 22/130 reads (17%) | called by muse, mutect2, varscan2
- MIR6859-4 | chr16:14385 G>A | 3'Flank (SNP) | VAF 80/211 reads (38%) | catalogued as rs765124820; called by muse, mutect2, varscan2
- MIRLET7BHG | n.253C>T | RNA (SNP) | VAF 38/231 reads (16%) | catalogued as rs1350051079; called by muse, mutect2, varscan2
- MIRLET7BHG | n.254C>T | RNA (SNP) | VAF 39/234 reads (17%) | catalogued as rs748283895; called by muse, mutect2, varscan2
- MMAB | c.*851G>A | 3'UTR (SNP) | VAF 9/75 reads (12%) | catalogued as rs1190420023; called by muse, mutect2, varscan2
- NCF1B | n.546G>A | RNA (SNP) | VAF 34/179 reads (19%) | catalogued as rs781834647; called by mutect2, varscan2
- NDUFV3 | c.170-5212C>T | Intron (SNP) | VAF 112/547 reads (20%) | called by muse, mutect2, varscan2
- NTM-AS1 | n.2248G>A | RNA (SNP) | VAF 17/135 reads (13%) | catalogued as rs1392789959; called by muse, mutect2, varscan2
- OSBPL2 | chr20:62233307 C>T | 5'Flank (SNP) | VAF 16/151 reads (11%) | called by muse, mutect2, varscan2
- OSCP1 | c.-2C>T | 5'UTR (SNP) | VAF 21/106 reads (20%) | catalogued as rs957919095; called by muse, mutect2
- OTOF | c.*153C>T | 3'UTR (SNP) | VAF 29/134 reads (22%) | called by muse, mutect2, varscan2
- PECAM1 | c.*1929G>A | 3'UTR (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- PICK1 | c.835-9C>T | Intron (SNP) | VAF 55/224 reads (25%) | called by muse, mutect2, varscan2
- RARG | c.185-4243G>A | Intron (SNP) | VAF 24/111 reads (22%) | called by muse, mutect2, varscan2
- REG1B | c.433+68G>A | Intron (SNP) | VAF 18/129 reads (14%) | called by muse, mutect2, varscan2
- RN7SL319P | chr15:75782856 C>T | 5'Flank (SNP) | VAF 44/315 reads (14%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.2778C>T | RNA (SNP) | VAF 21/125 reads (17%) | called by muse, mutect2, varscan2
- RNPS1 | c.*43C>T | 3'UTR (SNP) | VAF 33/152 reads (22%) | called by muse, mutect2, varscan2
- RPL23AP42 | n.143G>A | RNA (SNP) | VAF 57/441 reads (13%) | catalogued as rs367549517; called by muse, mutect2, varscan2
- SCN4B | c.*1826C>T | 3'UTR (SNP) | VAF 34/160 reads (21%) | called by muse, mutect2, varscan2
- SOX18 | c.*38C>T | 3'UTR (SNP) | VAF 61/427 reads (14%) | catalogued as rs947746370; called by muse, mutect2, varscan2
- SPON1 | c.-1G>A | 5'UTR (SNP) | VAF 38/159 reads (24%) | called by muse, mutect2, varscan2
- SSPOP | n.1902G>A | RNA (SNP) | VAF 28/163 reads (17%) | catalogued as rs768750136; called by muse, mutect2, varscan2
- STK11IP | c.946-26C>T | Intron (SNP) | VAF 25/119 reads (21%) | called by muse, mutect2, varscan2
- STUB1 | chr16:684464 G>A | 3'Flank (SNP) | VAF 43/213 reads (20%) | called by muse, mutect2, varscan2
- SULT1A1 | chr16:28610182 A>G | 5'Flank (SNP) | VAF 23/186 reads (12%) | called by muse, mutect2, varscan2
- TGM2 | c.1616-133G>A | Intron (SNP) | VAF 12/60 reads (20%) | catalogued as rs1322844835; called by muse, mutect2, varscan2
- TMTC4 | c.-54-1571G>A | Intron (SNP) | VAF 18/119 reads (15%) | called by muse, mutect2, varscan2
- TNS2 | c.696+39C>T | Intron (SNP) | VAF 60/458 reads (13%) | called by muse, mutect2, varscan2
- TRBV25OR9-2 | n.228C>T | RNA (SNP) | VAF 46/299 reads (15%) | called by muse, mutect2, varscan2
- TSKS | c.663+176C>T | Intron (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- TSPAN32 | c.354+522C>T | Intron (SNP) | VAF 34/184 reads (18%) | called by muse, mutect2, varscan2
- TTC4 | c.111+21C>T | Intron (SNP) | VAF 31/170 reads (18%) | catalogued as rs1293429404; called by muse, mutect2, varscan2
- TTLL5 | c.-67C>T | 5'UTR (SNP) | VAF 16/137 reads (12%) | called by muse, mutect2, varscan2
- WASH8P | n.1387G>A | RNA (SNP) | VAF 236/1052 reads (22%) | called by muse, mutect2, varscan2
- ZNF461 | c.*836C>T | 3'UTR (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
